Somatic mutation profile of tumor specimen TCGA-78-7150-01A (aliquot TCGA-78-7150-01A-21D-2036-08) from TCGA case TCGA-78-7150, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.9 years (21,891 days).
Specimen TCGA-78-7150-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f52a503c-8fb9-457c-addc-6b643b15d77c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7150-10A (Blood Derived Normal), aliquot TCGA-78-7150-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5900ade-7e1e-4cd0-a857-a2571472733d

The open-access MAF lists 451 somatic variants for this specimen: 332 protein-altering or splice-affecting, 108 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 108, Nonsense Mutation 27, Frame Shift Del 13, Splice Site 6, Intron 5, RNA 3, Splice Region 2, In Frame Del 1, 5'Flank 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2278+1G>T p.X760_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | catalogued as COSV52195613; called by muse, mutect2, varscan2
- ABCB7 | c.2014G>C p.D672H (on ENST00000373394 / NM_001271696.3; = p.D673H on NM_004299.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV53718204, COSV53721389; called by muse, mutect2, varscan2
- ABCB9 | c.1878G>A p.M626I (on ENST00000280560 / NM_019625.4; = p.M583I on NM_019624.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV54890418; called by muse, mutect2
- ABHD14B | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1010712314, COSV56472283; called by mutect2, varscan2
- ACSM2B | c.159C>A p.H53Q | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61656985; called by muse, mutect2, varscan2
- ADAM12 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs377630592, COSV100901571; called by muse, mutect2, varscan2
- ADAM22 | c.573A>C p.R191S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV55970944; called by muse, mutect2
- ADAMTS12 | c.4621A>C p.K1541Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV61256658; called by muse, mutect2, varscan2
- ADAMTS15 | c.2429C>G p.S810C | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV54503476; called by muse, varscan2
- ADAMTS16 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56980219; called by muse, mutect2, varscan2
- ADCY2 | c.2856C>G p.S952R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV57860831; called by muse, mutect2
- ADGRG3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV59650321; called by muse, mutect2, varscan2
- AHNAK2 | c.3841G>A p.E1281K | Missense Mutation (SNP) | VAF 104/188 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as COSV60909037; called by muse, mutect2, varscan2
- AIM2 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV63698429, COSV63700826; called by muse, varscan2
- AKR1B1 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV53646536; called by muse, mutect2
- ALG10B | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs759172569, COSV58142481; called by muse, mutect2, varscan2
- ALX4 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV61325065, COSV61327067; called by muse, mutect2, varscan2
- AMPD1 | c.2243T>C p.I748T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62415183; called by muse, mutect2, varscan2
- AMPH | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV57734519; called by muse, mutect2, varscan2
- ANKRD30A | c.523C>A p.P175T (on ENST00000611781; = p.P119T on NM_052997.2) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs879046249, COSV64605181, COSV64615803; called by muse, mutect2, varscan2
- ANKRD50 | c.3244A>G p.M1082V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.055); catalogued as rs200654829; called by muse, mutect2, varscan2
- ANKS1A | c.3212C>T p.S1071F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV64459079; called by muse, mutect2, varscan2
- APBB1IP | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV66130779; called by muse, mutect2, varscan2
- APCS | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs151221908, COSV54819445; called by muse, mutect2, varscan2
- ART5 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.456); catalogued as COSV63364122; called by muse, mutect2, varscan2
- ASIC2 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV63296666; called by muse, mutect2, varscan2
- ASZ1 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99498322; called by muse, mutect2, varscan2
- ATOH1 | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV60037486; called by muse, mutect2, varscan2
- ATP1A4 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625648; called by muse, mutect2, varscan2
- ATR | c.2083A>G p.K695E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV63384471; called by muse, mutect2, varscan2
- B4GALT5 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367589949; called by muse, mutect2, varscan2
- BBS5 | c.766G>C p.V256L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV54752092; called by muse, mutect2, varscan2
- BCL2L1 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV56966487; called by muse, mutect2, varscan2
- BRINP2 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV64175873; called by muse, mutect2, varscan2
- BRWD3 | c.5228G>A p.R1743K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV64744446; called by muse, mutect2, varscan2
- BTBD16 | c.1147G>T p.G383W | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53261021, COSV99584446; called by muse, mutect2, varscan2
- C14orf93 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); catalogued as COSV54440428; called by muse, mutect2, varscan2
- C6orf118 | c.875A>T p.K292M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57812894; called by muse, mutect2
- CA9 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65675077; called by muse, mutect2, varscan2
- CACNA1D | c.4526T>A p.L1509H (on ENST00000350061 / NM_001128840.3; = p.L1529H on NM_000720.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55439285; called by muse, mutect2, varscan2
- CAPN6 | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100137106; called by muse, mutect2, varscan2
- CAPN6 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100136822; called by muse, mutect2, varscan2
- CARMIL3 | c.1828T>G p.S610A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV57725221; called by muse, mutect2, varscan2
- CASKIN1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750494516, COSV58870367; called by muse, mutect2, varscan2
- CCDC54 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53758095, COSV53758684, COSV99660233; called by muse, mutect2, varscan2
- CCDC66 | c.1307G>A p.S436N (on ENST00000394672 / NM_001353147.1; = p.S402N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs769409874, COSV58301747; called by muse, mutect2, varscan2
- CD163 | c.3426G>T p.K1142N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as COSV63130003; called by muse, mutect2, varscan2
- CDH18 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56904804; called by muse, mutect2, varscan2
- CELSR3 | c.8888G>A p.C2963Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV50841138; called by muse, mutect2, varscan2
- CFAP94 | c.647G>T p.W216L (on ENST00000320267 / NM_001352064.2; = p.W222L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100209765; called by muse, mutect2, varscan2
- CHAF1B | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.263); catalogued as COSV58439358; called by muse, mutect2, varscan2
- CHMP5 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV56302668; called by muse, mutect2, varscan2
- CHRDL1 | c.409A>T p.T137S (on ENST00000372045; = p.T143S on NM_145234.4) | Missense Mutation (SNP) | VAF 124/197 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54323144; called by muse, mutect2, varscan2
- COL14A1 | c.4885C>T p.Q1629* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV52848272; called by muse, mutect2, varscan2
- COL4A2 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); catalogued as rs751105211, COSV64625363; called by muse, mutect2, varscan2
- COL6A2 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56000304; called by muse, mutect2, varscan2
- COL6A3 | c.6283-1G>A p.X2095_splice | Splice Site (SNP) | VAF 25/183 reads (14%) | catalogued as COSV55081294; called by muse, mutect2, varscan2
- COX10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs764489645, COSV55402642; called by muse, mutect2, varscan2
- CPEB4 | c.1252A>G p.I418V | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV54169979; called by muse, mutect2, varscan2
- CTTN | c.1387G>C p.A463P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV57230549, COSV57236943; called by muse, mutect2, varscan2
- CX3CR1 | c.1034A>T p.H345L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV64193212, COSV64194876; called by muse, mutect2, varscan2
- CYP26C1 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as COSV53651885; called by muse, mutect2, varscan2
- CYP2C18 | c.1071A>C p.R357S | Missense Mutation (SNP) | VAF 96/166 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53670079; called by muse, mutect2, varscan2
- DCBLD2 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV58787749; called by muse, mutect2, varscan2
- DCDC1 | c.2992G>T p.E998* (on ENST00000597505 / NM_001367979.1; = p.E105* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 39/115 reads (34%) | catalogued as rs998182775, COSV60304048; called by muse, mutect2, varscan2
- DDX60L | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as COSV52709764; called by muse, mutect2, varscan2
- DEPDC5 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56692252; called by muse, mutect2, varscan2
- DGKG | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1193182551, COSV53962067; called by muse, mutect2, varscan2
- DISC1 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.346); catalogued as COSV54401662; called by muse, mutect2, varscan2
- DKK2 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53394617, COSV53399664; called by muse, mutect2, varscan2
- DLK1 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57990775; called by muse, mutect2, varscan2
- DNAH10 | c.9970A>T p.R3324W (on ENST00000409039; = p.R3263W on NM_207437.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV68988926; called by muse, mutect2
- DNAI4 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV64020841; called by muse, mutect2, varscan2
- DSCAML1 | c.1238A>C p.E413A (on ENST00000321322; = p.E353A on NM_020693.4) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV58383021; called by muse, mutect2, varscan2
- DSP | c.4693G>C p.E1565Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as COSV65791468; called by muse, mutect2, varscan2
- DTNA | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV51992666; called by muse, mutect2, varscan2
- EEF1AKNMT | c.742G>T p.E248* (on ENST00000361735 / NM_015935.5; = p.E162* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV62282557; called by muse, mutect2, varscan2
- EEF1B2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51908318; called by muse, mutect2
- EFCAB6 | c.2416T>G p.C806G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV53059093; called by muse, mutect2, varscan2
- EFEMP2 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57259249; called by muse, mutect2, varscan2
- EIF4G3 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV51675375; called by muse, mutect2, varscan2
- ELAPOR2 | c.2797G>A p.G933S (on ENST00000450689 / NM_001142749.3; = p.G766S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.631); catalogued as rs776339060, COSV51884564, COSV51891560, COSV99788294; called by muse, mutect2, varscan2
- EPHA3 | c.1958A>G p.K653R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1465477687, COSV60695814; called by muse, mutect2, varscan2
- EPHA3 | c.2415C>G p.S805R | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60692794, COSV60695820; called by muse, mutect2, varscan2
- EPRS1 | c.3373G>C p.V1125L | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65097396; called by muse, mutect2, varscan2
- EZR | c.1650T>A p.N550K | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV51908386, COSV99791516; called by muse, mutect2, varscan2
- FAM135B | c.2122C>G p.P708A | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV52708388, COSV52748990; called by muse, mutect2, varscan2
- FAM170A | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs745479291, COSV58924182; called by muse, mutect2, varscan2
- FAM83B | c.2491A>G p.K831E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV60919782; called by muse, mutect2, varscan2
- FAT3 | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV53081548; called by muse, mutect2, varscan2
- FAT3 | c.7885G>A p.D2629N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs758444854, COSV53081574; called by muse, mutect2
- FAT4 | c.4964G>T p.S1655I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV67882060; called by muse, mutect2
- FBXO5 | c.667A>C p.I223L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57670458; called by muse, mutect2, varscan2
- FCRL2 | c.129C>A p.N43K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV63832837; called by muse, mutect2, varscan2
- FGA | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as CD035514, COSV57393503, COSV57402272; called by muse, mutect2, varscan2
- FIGNL2 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73729208; called by muse, mutect2, varscan2
- FMN2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs747413802, COSV100146867, COSV60447753; called by muse, mutect2, varscan2
- FRY | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs749362530, COSV66566035; called by muse, mutect2, varscan2
- FRYL | c.5867G>C p.R1956P | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51940917; called by muse, mutect2, varscan2
- FUT9 | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100134059, COSV56142884; called by muse, mutect2, varscan2
- GAB1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV53754837; called by muse, mutect2, varscan2
- GAB2 | c.307G>A p.E103K (on ENST00000361507 / NM_080491.3; = p.E65K on NM_012296.3) | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV60866293; called by muse, mutect2, varscan2
- GALNT13 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV67211407; called by muse, mutect2, varscan2
- GALNT2 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1161216760, COSV64193176; called by muse, mutect2, varscan2
- GAN | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV73720751; called by muse, mutect2
- GBP4 | c.1527G>A p.M509I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1352453832, COSV63253140; called by muse, mutect2, varscan2
- GCC1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs760413694, COSV50000380; called by muse, mutect2, varscan2
- GCM1 | c.826A>G p.S276G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1248429897, COSV52521030, COSV99452676; called by muse, mutect2, varscan2
- GJA8 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53787927; called by muse, mutect2, varscan2
- GLDC | c.1138A>T p.N380Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58676934; called by muse, mutect2, varscan2
- GPR158 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV66266144; called by muse, mutect2, varscan2
- GPRIN3 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV60884242; called by muse, mutect2, varscan2
- GTF3C1 | c.2596A>G p.T866A | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV62239271; called by muse, mutect2, varscan2
- GUCY1A1 | c.1631C>A p.T544N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV56649571; called by muse, mutect2, varscan2
- H1-3 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55096696; called by muse, mutect2, varscan2
- H2AC16 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as rs184589037, COSV58899169; called by muse, mutect2, varscan2
- HCLS1 | c.1025del p.P342Qfs*113 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | catalogued as rs759748703, COSV57525820; called by mutect2, pindel, varscan2
- HEXIM1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs767754935, COSV60176721; called by muse, varscan2
- HIP1 | c.2739C>G p.S913R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61183616; called by muse, mutect2, varscan2
- HIVEP3 | c.5174G>T p.G1725V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV56010513; called by muse, mutect2, varscan2
- HOXA5 | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56072407; called by muse, mutect2, varscan2
- HOXB8 | c.89A>C p.Q30P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.921); catalogued as COSV53309944; called by muse, mutect2, varscan2
- HUS1B | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.099); catalogued as COSV100034258; called by muse, mutect2, varscan2
- IFI16 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as COSV55531544, COSV55532858; called by muse, mutect2, varscan2
- IMPG2 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51974289; called by muse, mutect2, varscan2
- INSR | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV57158589; called by muse, mutect2, varscan2
- ITGB1BP2 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52135964; called by muse, mutect2, varscan2
- IVL | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as COSV64215657; called by muse, mutect2, varscan2
- JAKMIP2 | c.2293T>A p.Y765N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.221); catalogued as COSV54596803, COSV54598546; called by muse, mutect2, varscan2
- KLHDC2 | c.566G>T p.R189I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100027150, COSV53588037; called by muse, mutect2, varscan2
- KLHDC2 | c.567A>T p.R189S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV100027152; called by muse, mutect2, varscan2
- KLHL32 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV65110664; called by muse, mutect2
- KNG1 | c.930G>A p.Q310= | Splice Region (SNP) | VAF 27/87 reads (31%) | catalogued as rs748883626, COSV53976310; called by muse, mutect2, varscan2
- LCOR | c.3357G>A p.M1119I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs1488673158, COSV53714606; called by muse, mutect2, varscan2
- LDLRAD1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64955798, COSV64955808; called by muse, mutect2, varscan2
- LGSN | c.1513T>A p.L505I | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV65726360; called by muse, mutect2, varscan2
- LILRA4 | c.605C>A p.T202N | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as COSV52490557; called by muse, mutect2, varscan2
- LLGL2 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs988742283, COSV51342831, COSV51414643; called by muse, mutect2
- LRIG2 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63161178; called by muse, mutect2, varscan2
- LRRC4B | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65349353; called by muse, mutect2, varscan2
- LTBP2 | c.4600G>A p.D1534N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.729); catalogued as COSV56205605; called by muse, mutect2, varscan2
- MAGEC1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV53568887; called by muse, mutect2, varscan2
- MAGOH | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV65161109; called by muse, mutect2, varscan2
- MDN1 | c.10550A>T p.D3517V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV65517997, COSV65528897; called by muse, mutect2, varscan2
- MED24 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1442230131, COSV62417434; called by muse, mutect2, varscan2
- MEIS2 | c.701G>T p.G234V (on ENST00000561208 / NM_170675.5; = p.G221V on NM_002399.3) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV54931911, COSV54934277; called by muse, mutect2, varscan2
- MFSD14A | c.1383G>A p.W461* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV54926723; called by muse, mutect2, varscan2
- MGAT4B | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.679); catalogued as rs771976741, COSV52976919; called by muse, mutect2, varscan2
- MGAT4C | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152922, COSV59830390; called by muse, mutect2, varscan2
- MOGAT1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV71479820; called by muse, mutect2, varscan2
- MPDZ | c.5363T>G p.V1788G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59915735; called by muse, mutect2, varscan2
- MROH2B | c.4021C>T p.H1341Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs368816862; called by muse, mutect2, varscan2
- MSN | c.856G>T p.G286W | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64303433; called by muse, mutect2, varscan2
- MTRR | c.84G>T p.M28I (on ENST00000264668; = p.M1? on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV52941985, COSV52942816; called by muse, mutect2, varscan2
- MUC16 | c.9976G>A p.G3326R | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.467); catalogued as COSV67448560; called by muse, mutect2, varscan2
- MUC16 | c.8941G>T p.G2981* | Nonsense Mutation (SNP) | VAF 54/112 reads (48%) | catalogued as COSV67448567; called by muse, mutect2, varscan2
- MUC3A | c.7043C>T p.T2348I | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious, low confidence (0); catalogued as COSV60211426; called by muse, mutect2, varscan2
- MYBPC3 | c.2806A>T p.T936S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57023859, COSV99920378; called by muse, mutect2, varscan2
- MYLK | c.4839G>A p.E1613= | Splice Region (SNP) | VAF 8/56 reads (14%) | catalogued as COSV60605548; called by muse, mutect2, varscan2
- MYO18B | c.5689G>C p.D1897H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59127000, COSV59149826; called by muse, mutect2, varscan2
- NAF1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV56803436; called by muse, mutect2
- NALCN | c.2260C>T p.L754F | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.706); catalogued as COSV51920769; called by muse, mutect2, varscan2
- NAT10 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV57662609; called by muse, mutect2, varscan2
- NDC80 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs1334831309, COSV55247123, COSV55249129; called by muse, mutect2, varscan2
- NECTIN3 | c.440T>A p.I147N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV60550090; called by muse, mutect2, varscan2
- NET1 | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV61790914; called by muse, mutect2, varscan2
- NOP14 | c.1891+2T>A p.X631_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV58624136; called by muse, mutect2, varscan2
- NOTCH4 | c.5998G>A p.E2000K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV66679079, COSV66681490; called by muse, mutect2, varscan2
- NOVA1 | c.304A>T p.I102F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57473011; called by muse, mutect2, varscan2
- NRP1 | c.1967C>G p.S656C | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV55160899; called by muse, mutect2, varscan2
- OFD1 | c.1902G>T p.R634S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV60794633; called by muse, mutect2, varscan2
- OR10G4 | c.263del p.G88Afs*47 | Frame Shift Del (DEL) | VAF 21/148 reads (14%) | catalogued as COSV100305056; called by pindel, varscan2
- OR10G4 | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs774037985, COSV57976816; called by muse, mutect2, varscan2
- OR2A4 | c.688A>G p.R230G | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59575658; called by muse, mutect2, varscan2
- OR2L2 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV63548905; called by muse, mutect2, varscan2
- OR3A2 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV68694960, COSV68695094; called by muse, mutect2, varscan2
- OR4A5 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.793); catalogued as rs138866955; called by muse, mutect2, varscan2
- OR51S1 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV59057428; called by muse, mutect2, varscan2
- OR5J2 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV56620264; called by muse, mutect2, varscan2
- OR8D4 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as COSV100361960, COSV58431603; called by muse, varscan2
- OR8D4 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100361964; called by muse, varscan2
- OSBPL1A | c.2464G>A p.E822K (on ENST00000319481 / NM_080597.4; = p.E309K on NM_018030.4) | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60195751; called by muse, mutect2
- OTOGL | c.5901G>C p.Q1967H (on ENST00000547103; = p.Q1958H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV100087937, COSV54015211; called by muse, mutect2, varscan2
- PAPPA2 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV62773986; called by muse, mutect2, varscan2
- PAPPA2 | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 52/213 reads (24%) | catalogued as COSV62773994, COSV62777102; called by muse, mutect2, varscan2
- PASD1 | c.100A>T p.N34Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV64854283; called by muse, mutect2
- PCDH17 | c.2034G>C p.K678N | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.821); catalogued as COSV64972167; called by muse, mutect2, varscan2
- PCDHA4 | c.2189G>C p.G730A | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV63539353, COSV63547136; called by muse, mutect2, varscan2
- PCDHB14 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV53386803, COSV53388667; called by muse, mutect2, varscan2
- PCDHGA8 | c.1604G>T p.S535I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.19); catalogued as COSV99547392; called by muse, mutect2, varscan2
- PDCD5 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 80/123 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1340372783, COSV55678038; called by muse, mutect2, varscan2
- PDE3B | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV56380221; called by muse, mutect2
- PDLIM3 | c.401T>C p.I134T (on ENST00000284770 / NM_001257963.1; = p.I301T on NM_014476.6) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV52977997; called by muse, mutect2, varscan2
- PGD | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV54620408; called by muse, mutect2, varscan2
- PGR | c.2717del p.P906Qfs*3 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV54809400; called by mutect2, pindel, varscan2
- PLA2R1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV51775501; called by muse, mutect2, varscan2
- PLK1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV55620930; called by muse, mutect2, varscan2
- PNPT1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1324556801, COSV53175933; called by muse, mutect2, varscan2
- POLQ | c.5962G>C p.D1988H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51746952; called by muse, mutect2
- PPP4R1 | c.134T>C p.L45S (on ENST00000400556 / NM_001042388.3; = p.L28S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53280650; called by muse, mutect2, varscan2
- PROX2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs768044735, COSV71519982; called by muse, mutect2, varscan2
- PRRC2A | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65685345; called by muse, mutect2, varscan2
- PTH2R | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599176, COSV55913684; called by muse, mutect2, varscan2
- RAB6B | c.495+1G>T p.X165_splice | Splice Site (SNP) | VAF 53/157 reads (34%) | catalogued as COSV53312331; called by muse, mutect2, varscan2
- RAD18 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53749308; called by muse, mutect2, varscan2
- RBAK | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1456489524, COSV62330894; called by muse, mutect2, varscan2
- RBPJ | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV60749282; called by muse, mutect2
- REG3A | c.360G>C p.W120C | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59408622; called by muse, mutect2, varscan2
- REV3L | c.8090G>C p.R2697T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62615936; called by muse, mutect2, varscan2
- RFTN1 | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV61917127; called by muse, mutect2, varscan2
- RIC3 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as COSV58300678; called by muse, mutect2, varscan2
- RORB | c.1240G>C p.D414H (on ENST00000396204 / NM_001365023.1; = p.D403H on NM_006914.4) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV65333240; called by muse, mutect2, varscan2
- RUNX1T1 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as COSV56139069; called by muse, mutect2, varscan2
- RXFP1 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs771304565, COSV57047272; called by muse, mutect2, varscan2
- RYR2 | c.824G>A p.W275* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV63666199; called by muse, mutect2, varscan2
- SAFB | c.1605G>C p.K535N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV52649952; called by muse, mutect2, varscan2
- SALL1 | c.2065T>C p.S689P | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51753999; called by muse, mutect2, varscan2
- SAMD9L | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV59079959; called by muse, mutect2, varscan2
- SAXO1 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs750990247, COSV65868678; called by muse, mutect2, varscan2
- SCAP | c.2981C>T p.A994V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs757920492, COSV55542929; called by muse, mutect2, varscan2
- SCRIB | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as COSV57582865; called by muse, mutect2, varscan2
- SCTR | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50027014; called by muse, mutect2, varscan2
- SELP | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as COSV55248880; called by muse, mutect2, varscan2
- SERTM1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV59375784; called by muse, mutect2, varscan2
- SETD2 | c.7046C>G p.A2349G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV57431525; called by muse, mutect2, varscan2
- SH2B1 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 124/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59460988, COSV59463416; called by muse, mutect2, varscan2
- SHPRH | c.2103T>A p.F701L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51605380, COSV99262210; called by muse, mutect2, varscan2
- SHPRH | c.1109T>G p.I370S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51605397; called by muse, mutect2, varscan2
- SHROOM4 | c.3474G>T p.E1158D | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56785256, COSV99173390; called by muse, mutect2, varscan2
- SLC13A2 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782367843, COSV58992985; called by muse, mutect2, varscan2
- SLC22A12 | c.1371C>G p.S457R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV100327878, COSV60571087; called by muse, mutect2, varscan2
- SLC24A5 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV58316380; called by muse, mutect2, varscan2
- SLC25A23 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51190551; called by muse, mutect2, varscan2
- SLC25A31 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1013234281, COSV55418127, COSV99829573; called by mutect2, varscan2
- SLC25A41 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58599242; called by muse, mutect2, varscan2
- SLC4A7 | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as rs772459349, COSV55395275; called by muse, mutect2, varscan2
- SLC5A12 | c.672T>A p.H224Q | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54819407; called by muse, mutect2, varscan2
- SLC5A9 | c.2006T>C p.L669S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52582283; called by muse, mutect2, varscan2
- SLC8B1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52526496; called by muse, mutect2, varscan2
- SLITRK3 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV53846061; called by muse, mutect2, varscan2
- SLITRK6 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68389503; called by muse, mutect2, varscan2
- SLX4 | c.4671A>C p.K1557N | Missense Mutation (SNP) | VAF 115/209 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53561345; called by muse, mutect2, varscan2
- SPHKAP | c.4300G>A p.D1434N | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60870248; called by muse, mutect2, varscan2
- ST18 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV52486064; called by muse, mutect2, varscan2
- STRBP | c.1775C>G p.A592G | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV62117175; called by muse, mutect2, varscan2
- STRN3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV62578599; called by muse, varscan2
- SUCLA2 | c.1059G>T p.M353I (on ENST00000643023; = p.M332I on NM_003850.3) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV66221916; called by muse, mutect2, varscan2
- SUPT6H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs897919382, COSV58924533; called by muse, mutect2, varscan2
- SYCP1 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV65694930; called by muse, mutect2, varscan2
- SYNE2 | c.6623A>T p.Y2208F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.815); catalogued as COSV59941376; called by muse, mutect2, varscan2
- SYNPO2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61107370; called by muse, mutect2, varscan2
- SYT9 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59614544, COSV59615180; called by muse, mutect2, varscan2
- SZT2 | c.9547G>C p.E3183Q (on ENST00000634258 / NM_001365999.1; = p.E3126Q on NM_015284.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65094205, COSV65095047; called by muse, mutect2, varscan2
- TACC2 | c.135A>T p.R45S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as COSV57747920; called by muse, mutect2, varscan2
- TAF1L | c.1786C>A p.Q596K | Missense Mutation (SNP) | VAF 71/809 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as rs934288455, COSV54258705; called by muse, mutect2
- TAS2R40 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV68818164; called by muse, mutect2, varscan2
- TBCCD1 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV58661658; called by muse, mutect2, varscan2
- TEKT5 | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs947689592, COSV51586939; called by muse, mutect2, varscan2
- TENM1 | c.6863G>A p.S2288N | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as rs368631244, COSV64426097; called by muse, mutect2, varscan2
- THEMIS | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64069509, COSV64072689; called by muse, mutect2, varscan2
- THOP1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs142015327, COSV100310825; called by muse, mutect2, varscan2
- THSD7B | c.477C>G p.C159W | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55659569, COSV55664345; called by muse, mutect2, varscan2
- TM7SF3 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV58001520; called by muse, mutect2, varscan2
- TMCC1 | c.1443G>T p.E481D (on ENST00000393238 / NM_001349268.2; = p.E157D on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV61438890; called by muse, mutect2, varscan2
- TMEM175 | c.291-2A>T p.X97_splice | Splice Site (SNP) | VAF 22/86 reads (26%) | catalogued as COSV53277672; called by muse, mutect2, varscan2
- TMEM175 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs371988711; called by muse, varscan2
- TOGARAM1 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV63890763; called by muse, mutect2, varscan2
- TRANK1 | c.4501G>A p.G1501S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57142660; called by muse, mutect2, varscan2
- TRPS1 | c.49G>T p.E17* (on ENST00000220888 / NM_001330599.2; = p.E30* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV55228483, COSV55238235; called by muse, mutect2, varscan2
- TRPV2 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV58427477; called by muse, mutect2, varscan2
- TSC22D4 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.101); catalogued as COSV55723515; called by muse, mutect2, varscan2
- TSHZ3 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 129/209 reads (62%) | catalogued as COSV53665549; called by muse, mutect2, varscan2
- TTC14 | c.2176G>C p.V726L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.045); catalogued as COSV56009739; called by muse, mutect2, varscan2
- TTC17 | c.282A>C p.E94D | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.358); catalogued as COSV50006363; called by muse, mutect2, varscan2
- TTC8 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100581130, COSV57626485; called by muse, mutect2, varscan2
- TTN | c.11358G>C p.L3786F (on ENST00000591111; = p.L3740F on NM_003319.4) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV59911401; called by muse, mutect2, varscan2
- UGDH | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV57096840; called by muse, mutect2, varscan2
- UGT2B11 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV71423050; called by muse, mutect2, varscan2
- USP26 | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV63708174; called by muse, mutect2, varscan2
- USP34 | c.10018G>C p.E3340Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV63724568; called by muse, mutect2, varscan2
- USP34 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101277296, COSV68398813; called by muse, mutect2
- USP35 | c.1497T>G p.I499M | Missense Mutation (SNP) | VAF 193/337 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV71572635; called by muse, mutect2, varscan2
- USP8 | c.1265G>C p.R422T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV56162665; called by muse, mutect2, varscan2
- UVSSA | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1394368435, COSV66229347; called by muse, mutect2, varscan2
- VAV2 | c.1944G>T p.K648N (on ENST00000371850 / NM_001134398.2; = p.K638N on NM_003371.4) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV64080349; called by muse, mutect2, varscan2
- VPS13D | c.7985G>C p.C2662S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.198); catalogued as COSV50624020; called by muse, mutect2, varscan2
- VPS50 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.823); catalogued as COSV58505986; called by muse, mutect2, varscan2
- WDR1 | c.1461G>T p.E487D (on ENST00000382452; = p.E347D on NM_005112.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV66723418; called by muse, mutect2, varscan2
- WDR72 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.388); catalogued as rs747582414, COSV64742242; called by muse, mutect2, varscan2
- WNT10B | c.551C>G p.S184* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56404937; called by muse, mutect2, varscan2
- XK | c.1274G>T p.S425I | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV66119778; called by muse, mutect2, varscan2
- XRCC2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV63770004; called by muse, mutect2, varscan2
- XRCC6 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63752438; called by muse, mutect2
- ZAN | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.77); catalogued as COSV61805686; called by muse, mutect2, varscan2
- ZBBX | c.2006C>A p.A669D | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV56783865; called by muse, mutect2, varscan2
- ZFHX4 | c.7184C>A p.P2395H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50534879; called by muse, mutect2, varscan2
- ZFP91 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60157639; called by muse, mutect2, varscan2
- ZGPAT | c.1343G>T p.S448I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56648741; called by muse, mutect2, varscan2
- ZGRF1 | c.5232G>T p.Q1744H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs1459364740, COSV71392962; called by muse, mutect2, varscan2
- ZGRF1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV52199149; called by muse, mutect2, varscan2
- ZIC1 | c.542T>A p.V181E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51551265; called by muse, mutect2, varscan2
- ZIM3 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 73/121 reads (60%) | catalogued as COSV54140448; called by muse, mutect2, varscan2
- ZNF227 | c.1335C>G p.F445L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV57311414; called by muse, mutect2, varscan2
- ZNF227 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV57311428; called by muse, mutect2, varscan2
- ZNF234 | c.1467C>A p.C489* | Nonsense Mutation (SNP) | VAF 62/92 reads (67%) | catalogued as COSV70602904, COSV70603154; called by muse, mutect2, varscan2
- ZNF33A | c.758G>A p.R253K (on ENST00000458705 / NM_006974.3; = p.R254K on NM_006954.2) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV56723515; called by muse, mutect2, varscan2
- ZNF461 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV64452999; called by muse, mutect2, varscan2
- ZNF461 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV64453015; called by muse, mutect2, varscan2
- ZNF521 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as COSV64122870, COSV64127125; called by muse, mutect2, varscan2
- ZNF676 | c.1705G>C p.E569Q (on ENST00000650058; = p.E537Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68092337, COSV68094305; called by muse, mutect2, varscan2
- ZNF707 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.472); catalogued as rs782357335, COSV62311048; called by muse, mutect2, varscan2
- ZNF713 | c.415C>A p.H139N (on ENST00000633730 / NM_001366796.2; = p.H152N on NM_182633.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV70056436; called by muse, mutect2, varscan2
- ZNF804A | c.3180G>T p.M1060I | Missense Mutation (SNP) | VAF 86/127 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56437507; called by muse, mutect2, varscan2
- ARHGEF35 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- CABLES2 | c.1383del p.L462Ffs*235 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- DDR2 | c.966del p.V323Sfs*35 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- ENOX2 | c.1246del p.E416Kfs*17 (on ENST00000338144 / NM_001382520.1; = p.E387Kfs*17 on NM_006375.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- FAF1 | c.556_561del p.L186_Q187del | In Frame Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- IGKV6D-21 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- LIAS | c.39del p.R15Gfs*14 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- LILRB3 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- MMRN2 | c.795del p.D265Efs*73 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ROS1 | c.4062del p.F1354Lfs*35 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- RPL3 | c.129dup p.T44Hfs*65 | Frame Shift Ins (INS) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- RUNX3 | c.956_965del p.Q319Pfs*56 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- SLC9A9 | c.1594_1598del p.F532Pfs*21 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1166C>A p.S389* | Nonsense Mutation (SNP) | VAF 24/240 reads (10%) | called by muse, varscan2
- TOX2 | c.320del p.G107Afs*27 (on ENST00000358131 / NM_001098798.2; = p.G56Afs*27 on NM_032883.3) | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- VWC2 | c.826+3_826+6del p.X276_splice | Splice Site (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- ZFP57 | c.1030del p.Q344Rfs*11 | Frame Shift Del (DEL) | VAF 23/180 reads (13%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1140G>A p.R380= | Silent (SNP) | VAF 130/387 reads (34%) | catalogued as COSV56642302; called by muse, mutect2, varscan2
- ACSS2 | c.444C>T p.F148= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV53623067; called by muse, mutect2, varscan2
- ADAM12 | c.564C>T p.L188= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as rs1454118681, COSV100901576; called by muse, mutect2, varscan2
- AMY2B | c.624G>T p.G208= | Silent (SNP) | VAF 49/370 reads (13%) | catalogued as COSV63714263; called by muse, mutect2, varscan2
- ANKRD35 | c.636G>A p.A212= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs375287957, COSV62910591; called by muse, mutect2, varscan2
- AP5M1 | c.657C>T p.S219= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1463465430, COSV55104583; called by muse, mutect2, varscan2
- ART1 | c.327C>G p.G109= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV51703077; called by muse, mutect2, varscan2
- ASZ1 | c.921C>T p.T307= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99498318; called by muse, mutect2, varscan2
- ATP12A | c.324C>G p.L108= | Silent (SNP) | VAF 61/362 reads (17%) | catalogued as COSV54513065; called by muse, mutect2, varscan2
- BIRC6 | c.13002C>T p.V4334= | Silent (SNP) | VAF 6/103 reads (6%) | catalogued as COSV70196132; called by muse, mutect2
- CACNA1S | c.4140C>A p.I1380= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV62936817; called by muse, mutect2, varscan2
- CACTIN | c.345A>G p.A115= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV50266917; called by muse, mutect2, varscan2
- CAPN10 | c.180A>T p.P60= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV54375020; called by muse, mutect2
- CCKAR | c.240C>T p.L80= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs762000293, COSV55160210; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4851C>T p.S1617= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs746393986, COSV62572390; called by muse, mutect2, varscan2
- CHPF | c.1717C>T p.L573= | Silent (SNP) | VAF 47/75 reads (63%) | catalogued as COSV60533739; called by muse, mutect2, varscan2
- CNBD2 | c.942T>C p.D314= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs772095400, COSV62586436; called by muse, varscan2
- COL22A1 | c.1833G>A p.G611= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV57325753; called by muse, mutect2, varscan2
- CR1L | c.807T>C p.H269= | Silent (SNP) | VAF 62/213 reads (29%) | catalogued as rs1166081584, COSV54322968; called by muse, mutect2, varscan2
- CSMD3 | c.8772T>G p.P2924= (on ENST00000297405 / NM_001363185.1; = p.P2755= on NM_052900.3) | Silent (SNP) | VAF 70/118 reads (59%) | catalogued as COSV52114046, COSV52338774; called by muse, mutect2, varscan2
- CUL1 | c.12C>G p.T4= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV57387022; called by muse, mutect2, varscan2
- DCDC1 | c.3432G>A p.V1144= (on ENST00000597505 / NM_001367979.1; = p.V251= on NM_020869.3) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100337707, COSV60304035; called by mutect2, varscan2
- DCHS1 | c.8067G>A p.L2689= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV54996262; called by muse, mutect2
- DGLUCY | c.141C>T p.S47= | Silent (SNP) | VAF 64/111 reads (58%) | catalogued as COSV54086676, COSV54088981; called by muse, mutect2, varscan2
- DPPA4 | c.504G>T p.V168= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV59509447; called by muse, mutect2, varscan2
- DSC1 | c.2526T>C p.H842= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs139389841; called by muse, mutect2, varscan2
- DSP | c.4044G>C p.L1348= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV65791465; called by muse, mutect2, varscan2
- ERICH3 | c.435G>A p.P145= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs370906098, COSV58600685; called by muse, mutect2, varscan2
- EXT2 | c.27C>T p.I9= (on ENST00000343631; = p.I42= on NM_000401.3) | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs149841763, COSV59147326; called by muse, mutect2, varscan2
- FAM90A1 | c.948C>T p.P316= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV56710376; called by muse, mutect2, varscan2
- FBN2 | c.1659T>C p.P553= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV52495976; called by muse, mutect2, varscan2
- GABRA4 | c.945T>C p.Y315= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV51923326; called by muse, mutect2, varscan2
- GABRB1 | c.123G>T p.V41= | Silent (SNP) | VAF 61/243 reads (25%) | catalogued as COSV54972643; called by muse, mutect2, varscan2
- GCK | c.303G>A p.V101= | Silent (SNP) | VAF 45/187 reads (24%) | catalogued as COSV61752711; called by muse, mutect2, varscan2
- GSKIP | c.30A>T p.L10= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV68451279; called by muse, mutect2, varscan2
- HCN1 | c.1182C>G p.T394= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100302482, COSV57504508, COSV57532447; called by muse, mutect2, varscan2
- HFM1 | c.762A>G p.T254= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV54022431; called by muse, mutect2, varscan2
- HOMER2 | c.63G>A p.K21= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV58484575; called by muse, mutect2, varscan2
- IGKV2D-24 | c.198C>A p.G66= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as rs1408761408; called by muse, mutect2
- IGLV5-37 | c.132C>T p.P44= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs1372837439; called by muse, mutect2, varscan2
- IL7R | c.264A>G p.L88= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV57406279; called by muse, mutect2, varscan2
- ITPRID1 | c.2340C>T p.T780= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs769522510, COSV60070785; called by muse, mutect2, varscan2
- JARID2 | c.1443G>A p.L481= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV59186104; called by muse, mutect2, varscan2
- KCNH8 | c.2914C>A p.R972= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60457634; called by muse, mutect2, varscan2
- KCNJ3 | c.627C>A p.L209= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54532036; called by muse, mutect2, varscan2
- KIFAP3 | c.1323T>A p.I441= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV63031348; called by muse, mutect2, varscan2
- KLHL5 | c.1608C>T p.P536= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV54672025, COSV99786106; called by muse, mutect2, varscan2
- KMT2D | c.6993G>T p.L2331= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV56415534; called by muse, mutect2, varscan2
- KNG1 | c.1389T>C p.H463= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV53976322; called by muse, mutect2, varscan2
- L1CAM | c.2904C>T p.F968= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV62827054; called by muse, mutect2, varscan2
- LTF | c.564G>A p.L188= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs756717214, COSV51606073; called by muse, mutect2, varscan2
- MAPK12 | c.888G>A p.A296= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as rs561024779, COSV53132156; called by muse, mutect2, varscan2
- MDN1 | c.7494G>C p.L2498= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as COSV101021174, COSV65518002; called by muse, mutect2, varscan2
- MED1 | c.678C>G p.V226= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV56122705; called by muse, mutect2, varscan2
- MEIS2 | c.1182G>A p.Q394= | Silent (SNP) | VAF 130/252 reads (52%) | catalogued as COSV54931899; called by muse, mutect2, varscan2
- MPRIP | c.2640G>A p.L880= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57925740; called by muse, mutect2, varscan2
- MUC3A | c.8346C>A p.P2782= | Silent (SNP) | VAF 42/419 reads (10%) | catalogued as rs1228030277, COSV60211436; called by muse, mutect2
- MUC5B | c.7770C>G p.T2590= | Silent (SNP) | VAF 80/282 reads (28%) | catalogued as COSV71590367; called by muse, varscan2
- MYH8 | c.4500G>C p.T1500= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV67960719; called by muse, mutect2, varscan2
- NAALAD2 | c.648C>A p.I216= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV58959115; called by muse, mutect2, varscan2
- NEK10 | c.3297A>T p.T1099= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV55355664; called by muse, mutect2, varscan2
- NEMF | c.2427A>G p.K809= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs903407346, COSV53589592; called by muse, mutect2, varscan2
- NR3C2 | c.2805G>A p.V935= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs759337979, COSV60985996; called by muse, mutect2, varscan2
- OMD | c.604C>T p.L202= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV65020045; called by muse, mutect2, varscan2
- OR10S1 | c.735C>A p.A245= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV73342676; called by muse, mutect2, varscan2
- OR2M4 | c.156G>A p.E52= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as COSV100141580, COSV60707400; called by muse, mutect2, varscan2
- OR4E2 | c.639C>G p.A213= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV57731449; called by muse, mutect2, varscan2
- OR6V1 | c.867C>A p.T289= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV69236966; called by muse, mutect2, varscan2
- OR8D4 | c.120G>T p.V40= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs377190285; called by muse, varscan2
- OXCT1 | c.27C>T p.S9= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1446331509, COSV52167842; called by muse, mutect2, varscan2
- PCDHA9 | c.2199G>A p.A733= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs373763041; called by muse, mutect2, varscan2
- PCDHB7 | c.2028G>T p.A676= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV50755403; called by muse, mutect2, varscan2
- PCDHB9 | c.2073G>T p.V691= | Silent (SNP) | VAF 79/216 reads (37%) | catalogued as COSV53375967; called by muse, mutect2, varscan2
- PCDHGA8 | c.1605C>T p.S535= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV53971998; called by muse, mutect2, varscan2
- PCNT | c.6837C>T p.S2279= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV64025621; called by muse, mutect2, varscan2
- PDE8B | c.1140G>T p.L380= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV53732896; called by muse, mutect2, varscan2
- PEG3 | c.1428A>G p.R476= | Silent (SNP) | VAF 119/173 reads (69%) | catalogued as rs1185613086, COSV55626603; called by muse, mutect2, varscan2
- PLCL1 | c.2022G>A p.P674= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs558973603, COSV70822050; called by muse, mutect2, varscan2
- PLXNA2 | c.3999C>T p.P1333= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs943970423, COSV65438129; called by muse, mutect2, varscan2
- POGZ | c.2145A>T p.A715= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV55032906; called by muse, mutect2, varscan2
- PRAME | c.633G>A p.K211= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV67161093; called by muse, mutect2, varscan2
- PRLH | c.111C>T p.I37= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV51255381; called by muse, mutect2, varscan2
- PRR19 | c.477G>A p.Q159= | Silent (SNP) | VAF 57/80 reads (71%) | catalogued as rs1238859385, COSV56623921; called by muse, mutect2, varscan2
- RAB40AL | c.396C>T p.F132= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV54433668; called by muse, mutect2, varscan2
- RAPGEF1 | c.231C>T p.T77= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1466898857, COSV64698159; called by muse, mutect2, varscan2
- RASAL2 | c.1260G>C p.L420= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV62710494; called by muse, mutect2, varscan2
- REM1 | c.393G>A p.V131= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1264807612, COSV52427033, COSV99146901; called by muse, mutect2, varscan2
- RIMS1 | c.663C>A p.P221= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV53441846; called by muse, mutect2, varscan2
- ROBO4 | c.537C>A p.A179= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as COSV60621826; called by muse, mutect2
- RRBP1 | c.2088G>A p.A696= (on ENST00000377813 / NM_001365613.2; = p.A263= on NM_004587.3) | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs772859385, COSV55696500; called by muse, mutect2, varscan2
- RREB1 | c.1017G>A p.V339= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV58554206; called by muse, mutect2, varscan2
- RTTN | c.5973A>T p.S1991= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV55341951; called by muse, mutect2, varscan2
- SFR1 | c.297A>G p.Q99= (on ENST00000369727 / NM_001002759.1; = p.Q86= on NM_145247.4) | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV60478644; called by muse, mutect2, varscan2
- SLC15A1 | c.1530C>T p.I510= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV64730227; called by muse, mutect2, varscan2
- SPG11 | c.123C>G p.L41= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV55991537; called by muse, mutect2, varscan2
- TAP2 | c.903C>T p.P301= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV66498268; called by muse, mutect2, varscan2
- TIE1 | c.657C>T p.R219= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV65248693; called by muse, mutect2, varscan2
- TNR | c.3543G>A p.Q1181= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV54873065; called by muse, mutect2, varscan2
- TRAF2 | c.315C>T p.A105= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs768833371, COSV56036561; called by mutect2, varscan2
- TRANK1 | c.4230C>T p.I1410= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV57142688; called by muse, mutect2, varscan2
- TSBP1 | c.1554T>A p.G518= (on ENST00000617061; = p.G523= on NM_006781.5) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV66657824; called by muse, mutect2, varscan2
- TUBA3C | c.1224C>T p.Y408= | Silent (SNP) | VAF 61/200 reads (31%) | catalogued as rs753881610, COSV101313836, COSV68027678; called by muse, mutect2, varscan2
- UBQLN3 | c.717G>T p.R239= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV61163402; called by muse, mutect2, varscan2
- UGT1A7 | c.222G>A p.V74= | Silent (SNP) | VAF 26/225 reads (12%) | catalogued as COSV60832896; called by muse, mutect2, varscan2
- WDFY3 | c.5028G>A p.E1676= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV55694609, COSV99885799; called by muse, mutect2, varscan2
- ZNF479 | c.489C>A p.V163= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV58636378; called by muse, mutect2, varscan2
- ZNF573 | c.1848G>T p.G616= (on ENST00000536220 / NM_001172692.1; = p.G558= on NM_152360.3) | Silent (SNP) | VAF 79/110 reads (72%) | catalogued as COSV59823576; called by muse, mutect2, varscan2
- ZNF835 | c.1140C>T p.H380= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV73379216; called by muse, mutect2, varscan2
- AC024940.1 | n.3277T>C | RNA (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621778 T>A | 3'Flank (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54084798; called by muse, mutect2, varscan2
- BEND6 | chr6:56954595 G>C | 5'Flank (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- FAM78B | c.263+11229G>T | Intron (SNP) | VAF 9/12 reads (75%) | catalogued as COSV57975459; called by muse, mutect2, varscan2
- FBH1 | c.1+4836C>T | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100758951; called by muse, mutect2, varscan2
- IFTAP | c.-2G>A | 5'UTR (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100531396; called by muse, mutect2, varscan2
- MFSD4B | c.27+2599A>G | Intron (SNP) | VAF 55/138 reads (40%) | catalogued as COSV64348601; called by muse, mutect2, varscan2
- MIR124-1 | n.23A>T | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- NBPF25P | n.1038C>A | RNA (SNP) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- PTPRF | c.3974-828G>C | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100740933; called by muse, mutect2, varscan2
- RAVER1 | c.1431+277C>G | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as COSV53344045; called by muse, mutect2, varscan2
